Somatic mutation profile of tumor specimen C3L-02127-01 (aliquot CPT0130270009) from CPTAC case C3L-02127, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 66.8 years (24,389 days).
Specimen C3L-02127-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a856309c-8c01-4e8a-9d98-e3a006b0384a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02127-31 (Blood Derived Normal), aliquot CPT0130390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b5b1296-e330-4e01-ab63-a6f6c2130caf

The open-access MAF lists 252 somatic variants for this specimen: 163 protein-altering or splice-affecting, 62 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 62, Intron 12, Nonsense Mutation 10, RNA 7, Frame Shift Del 4, Splice Region 3, Frame Shift Ins 3, 5'UTR 2, 3'Flank 2, 5'Flank 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 102/1149 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- MAN2B1 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 213/704 reads (30%) | catalogued as rs1555709972, COSV99663894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 249/438 reads (57%) | catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.1732del p.L578Ffs*24 | Frame Shift Del (DEL) | VAF 36/285 reads (13%) | catalogued as COSV50738634; called by mutect2, pindel, varscan2
- ANKRD29 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs780842342, COSV52425624; called by muse, mutect2, varscan2
- AOC1 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 106/343 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs749760907, COSV100710664; called by muse, mutect2, varscan2
- ARHGAP18 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs780919086; called by muse, mutect2, varscan2
- ATXN7L3 | c.734C>T p.S245L (on ENST00000389384 / NM_001382309.1; = p.S252L on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1217484794; called by muse, mutect2, varscan2
- BARHL2 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778940530; called by muse, mutect2, varscan2
- CAV3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201893621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDHR2 | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs763466864; called by muse, mutect2
- CDYL2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1232689953; called by muse, mutect2, varscan2
- CKMT2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1042613615, COSV54172768; called by muse, mutect2, varscan2
- COL4A4 | c.2722C>G p.R908G | Missense Mutation (SNP) | VAF 258/662 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV61630362, COSV61631425; called by muse, mutect2, varscan2
- COL6A2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs369025432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO2B | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs267604301, COSV99029290; called by muse, mutect2, varscan2
- CTR9 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs753928657; called by muse, mutect2, varscan2
- DNAH3 | c.11935G>A p.V3979I | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs377222116, COSV54529299; called by muse, mutect2, varscan2
- DYTN | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101510798; called by muse, mutect2, varscan2
- EXD3 | c.2525G>T p.G842V | Missense Mutation (SNP) | VAF 99/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1564456258; called by muse, mutect2, varscan2
- FAM214B | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1356231474; called by muse, mutect2, varscan2
- FIP1L1 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as rs1182237812, COSV55785103; called by muse, mutect2
- GABRA4 | c.1646A>T p.K549I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV51926285; called by muse, mutect2
- GPR176 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs1183300899, COSV100137310; called by muse, mutect2, varscan2
- GRM3 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 123/404 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV64466918; called by muse, mutect2, varscan2
- GSDMD | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 109/197 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1341962217; called by muse, mutect2, varscan2
- HTR2C | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 94/177 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV99347862; called by muse, mutect2, varscan2
- HTR3C | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59174992; called by muse, mutect2, varscan2
- IGHV1-46 | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 552/996 reads (55%) | catalogued as rs377014204; called by muse, mutect2, varscan2
- KCNJ3 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV54547753; called by muse, mutect2, varscan2
- KIF4B | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 103/179 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as rs758992898, COSV101469213, COSV70530872; called by muse, mutect2, varscan2
- KRT72 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs766532753, COSV53373404; called by muse, mutect2, varscan2
- KRTAP5-9 | c.499T>A p.C167S | Missense Mutation (SNP) | VAF 329/495 reads (66%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.765); catalogued as rs1166733197; called by muse, mutect2, varscan2
- LRP6 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1044073435; called by muse, mutect2, varscan2
- LTBP4 | c.2668C>T p.P890S (on ENST00000308370 / NM_001042544.1; = p.P853S on NM_003573.2) | Missense Mutation (SNP) | VAF 70/1318 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs780942572; ClinVar: uncertain significance; called by muse, mutect2
- MAML2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 184/369 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1226491746; called by muse, mutect2, varscan2
- MCF2L | c.1305G>T p.E435D (on ENST00000375608; = p.E403D on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/453 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65052474; called by muse, mutect2, varscan2
- MECP2 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs193922678, CM1212526, COSV57653810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIDEAS | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 95/175 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.041); catalogued as rs568369589, COSV54095982; called by muse, mutect2, varscan2
- MSH4 | c.2477C>A p.A826E | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99078918; called by muse, mutect2, varscan2
- MYRF | c.256C>T p.R86C (on ENST00000278836 / NM_001127392.3; = p.R77C on NM_013279.4) | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs756028420, COSV53889178; called by muse, mutect2
- NCOA6 | c.3371C>A p.S1124* | Nonsense Mutation (SNP) | VAF 160/387 reads (41%) | catalogued as COSV100750042; called by muse, mutect2, varscan2
- NCOR1 | c.6091C>T p.P2031S | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs781041255; called by muse, mutect2
- NFKBID | c.170C>T p.A57V (on ENST00000396901; = p.A209V on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/759 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as rs766871867; called by muse, mutect2, varscan2
- NOTCH1 | c.6304C>T p.Q2102* | Nonsense Mutation (SNP) | VAF 161/395 reads (41%) | catalogued as COSV53046104; called by muse, mutect2, varscan2
- NRG2 | c.1431C>A p.N477K | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56832728; called by muse, mutect2, varscan2
- OR8K5 | c.647T>G p.V216G | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs749151515; called by muse, mutect2, varscan2
- OTOP3 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 24/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1480866881, COSV60913469; called by muse, mutect2
- PADI6 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.634); catalogued as COSV100639873; called by muse, mutect2, varscan2
- PBX4 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769287977; called by muse, mutect2, varscan2
- PCDHB5 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 308/871 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV50647129; called by muse, mutect2, varscan2
- PLEKHG4B | c.3721G>T p.E1241* (on ENST00000283426; = p.E1597* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 38/712 reads (5%) | catalogued as COSV52046628; called by muse, mutect2
- PREX1 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV64248911; called by muse, mutect2, varscan2
- PRR16 | c.464G>A p.R155Q (on ENST00000407149 / NM_001300783.2; = p.R132Q on NM_016644.2) | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as rs760368454, COSV65394805; called by muse, mutect2
- RARB | c.459G>T p.M153I (on ENST00000383772 / NM_001290216.2; = p.M146I on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100412515; called by muse, mutect2
- ROBO2 | c.3617G>T p.G1206V | Missense Mutation (SNP) | VAF 112/203 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV59918564; called by muse, mutect2, varscan2
- RPF1 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1166386851; called by mutect2, varscan2
- SEMA4A | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 74/819 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs758417711, COSV61774497; ClinVar: uncertain significance; called by muse, mutect2
- SLC26A7 | c.1830A>T p.T610= | Splice Region (SNP) | VAF 18/240 reads (8%) | catalogued as COSV52600725; called by muse, mutect2
- SLCO1A2 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV56601703; called by muse, mutect2, varscan2
- SLITRK5 | c.1853T>C p.V618A | Missense Mutation (SNP) | VAF 239/408 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs889373990; called by muse, mutect2, varscan2
- SPATA31E1 | c.3751C>G p.Q1251E | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.168); catalogued as COSV57790730; called by muse, mutect2, varscan2
- SRSF6 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs141371836; called by muse, mutect2, varscan2
- TBXA2R | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 256/709 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985466939, COSV100916270; called by muse, mutect2, varscan2
- TEKT1 | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs915971660; called by muse, mutect2, varscan2
- TMEM132C | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 131/248 reads (53%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.651); catalogued as COSV104408517; called by muse, mutect2, varscan2
- TRPS1 | c.1876G>A p.V626I (on ENST00000220888 / NM_001330599.2; = p.V639I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.019); catalogued as rs181507248, COSV55258232; called by muse, mutect2
- UNCX | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs1482734440; called by muse, mutect2, varscan2
- ZNF142 | c.2671G>A p.G891S (on ENST00000411696 / NM_001379660.1; = p.G691S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs778601907; called by muse, mutect2, varscan2
- ZNF730 | c.1000C>A p.H334N | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV74168149; called by muse, mutect2
- ZNF730 | c.1406C>A p.T469K | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1446396019; called by muse, mutect2, varscan2
- ABCA5 | c.2357del p.L786* | Frame Shift Del (DEL) | VAF 46/233 reads (20%) | called by mutect2, pindel, varscan2
- ABCB10 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 58/529 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ADAT3 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 116/349 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ARHGEF4 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 19/646 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ARMC4 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ASXL3 | c.2263A>G p.I755V | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTD | c.1188C>A p.H396Q | Missense Mutation (SNP) | VAF 92/140 reads (66%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1B | c.3694G>T p.V1232L | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.313); called by muse, mutect2
- CACNA1E | c.5267G>C p.C1756S | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CACNA1S | c.2761A>C p.M921L | Missense Mutation (SNP) | VAF 143/684 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5R2 | c.1042T>A p.S348T | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by mutect2, varscan2
- CHAF1A | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CNBD1 | c.1228C>G p.Q410E | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2
- COL12A1 | c.8868A>T p.R2956S | Missense Mutation (SNP) | VAF 246/562 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- COL4A5 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 170/259 reads (66%) | SIFT tolerated (0.44); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- COPB2 | c.297dup p.D100Rfs*18 | Frame Shift Ins (INS) | VAF 27/110 reads (25%) | called by mutect2, pindel, varscan2
- CTSE | c.908A>G p.Q303R (on ENST00000360218; = p.Q298R on NM_001910.4) | Missense Mutation (SNP) | VAF 223/439 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAH2 | c.7919T>C p.I2640T | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2
- DPPA3 | c.114A>G p.I38M | Missense Mutation (SNP) | VAF 131/399 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ECT2 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELP1 | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMD | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 13/395 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2
- ERICH6B | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 132/246 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ERN2 | c.567dup p.M190Hfs*105 | Frame Shift Ins (INS) | VAF 10/100 reads (10%) | called by mutect2, pindel
- EVX2 | c.380_381insG p.G129Rfs*9 | Frame Shift Ins (INS) | VAF 198/492 reads (40%) | called by mutect2, pindel, varscan2
- FAM76A | c.840C>A p.A280= | Splice Region (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- FCRLA | c.167T>C p.L56P (on ENST00000367959; = p.L33P on NM_032738.4) | Missense Mutation (SNP) | VAF 163/634 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- FSIP2 | c.10657A>G p.I3553V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GAA | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GOLGA8K | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 108/882 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, varscan2
- GPNMB | c.288T>A p.F96L | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRIN2B | c.1756A>G p.N586D | Missense Mutation (SNP) | VAF 202/688 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GRM6 | c.1354+1G>A p.X452_splice | Splice Site (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- GSAP | c.1910A>G p.Y637C | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GTF2IRD1 | c.2375A>G p.D792G (on ENST00000265755 / NM_016328.3; = p.D777G on NM_005685.4) | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GULP1 | c.126_134dup p.T43_V45dup | In Frame Ins (INS) | VAF 38/166 reads (23%) | called by mutect2, varscan2
- HDAC4 | c.3082_3101del p.W1028Nfs*41 | Frame Shift Del (DEL) | VAF 42/244 reads (17%) | called by mutect2, pindel
- HDGFL1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- IGSF1 | c.1795A>C p.N599H | Missense Mutation (SNP) | VAF 105/152 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITIH5 | c.917T>A p.M306K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- KALRN | c.1184A>C p.Q395P | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- KALRN | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, varscan2
- KCNU1 | c.382G>T p.V128F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KLHL32 | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAG3 | c.1193T>A p.L398Q | Missense Mutation (SNP) | VAF 94/741 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LY6L | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 219/371 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGI2 | c.155T>A p.V52E | Missense Mutation (SNP) | VAF 98/413 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MAN2C1 | c.1694A>T p.Q565L | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MBLAC1 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 22/598 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- MKKS | c.385_391del p.Y130Sfs*27 | Frame Shift Del (DEL) | VAF 91/332 reads (27%) | called by mutect2, pindel, varscan2
- MS4A14 | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- MYO15B | c.6396G>T p.K2132N | Missense Mutation (SNP) | VAF 304/678 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NAV3 | c.5173C>T p.P1725S | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- NEK7 | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 22/239 reads (9%) | called by muse, mutect2
- NLGN4X | c.1966A>G p.T656A | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NSRP1 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- NTF3 | c.73A>T p.S25C | Missense Mutation (SNP) | VAF 113/458 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- NUB1 | c.1844T>G p.L615R (on ENST00000568733 / NM_001243351.1; = p.L601R on NM_016118.4) | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP58 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- OR2G6 | c.290G>C p.C97S | Missense Mutation (SNP) | VAF 90/424 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OR6Y1 | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 281/570 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PCDHGA4 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- PCDHGA4 | c.2471T>C p.I824T | Missense Mutation (SNP) | VAF 51/444 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PLCE1 | c.5492A>C p.E1831A | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU3F4 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 128/180 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- PRPF38A | c.933T>A p.N311K | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PYHIN1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RAB36 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- RGS7 | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 319/666 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- RTN4RL2 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEL1L2 | c.1194T>A p.F398L | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SETD1B | c.286_297del p.Y96_P99del | In Frame Del (DEL) | VAF 70/111 reads (63%) | called by mutect2, pindel, varscan2
- SORCS1 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | called by muse, varscan2
- SOX14 | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 18/710 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- SPANXC | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SVIP | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SYNE1 | c.23431A>G p.I7811V (on ENST00000367255 / NM_182961.4; = p.I7740V on NM_033071.3) | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYNE2 | c.6263T>C p.L2088S | Missense Mutation (SNP) | VAF 165/280 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TCF7L1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- TGFB1I1 | c.731G>C p.G244A (on ENST00000394863 / NM_001042454.3; = p.G227A on NM_015927.4) | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM132D | c.1444-3C>T | Splice Region (SNP) | VAF 65/109 reads (60%) | called by muse, mutect2, varscan2
- TPTE | c.911T>A p.I304N (on ENST00000618007 / NM_199261.4; = p.I286N on NM_199259.4) | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRPM3 | c.1070C>T p.P357L (on ENST00000357533 / NM_001366142.2; = p.P202L on NM_020952.6) | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TTN | c.16390G>C p.E5464Q (on ENST00000591111; = p.E4537Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/369 reads (34%) | PolyPhen benign (0.308); called by muse, mutect2, varscan2
- UGT2B4 | c.521T>A p.F174Y | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- USP12 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- WDFY3 | c.9679G>C p.D3227H | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- WIPI2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- ZBED8 | c.845C>G p.T282R | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2
- ZNF280B | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ZNF687 | c.2918C>G p.P973R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF730 | c.1002T>A p.H334Q | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ALPG | c.1395G>A p.A465= | Silent (SNP) | VAF 110/686 reads (16%) | catalogued as rs750420048, COSV54967245; called by muse, mutect2, varscan2
- ANK3 | c.7503G>A p.R2501= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as rs770573699; called by muse, mutect2, varscan2
- ARHGAP18 | c.1770C>T p.S590= | Silent (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2, varscan2
- ASB7 | c.639C>T p.D213= | Silent (SNP) | VAF 31/250 reads (12%) | catalogued as rs757982775, COSV58404626; called by muse, mutect2, varscan2
- ATRN | c.3552T>C p.A1184= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs112500645; called by muse, mutect2, varscan2
- BRD2 | c.705C>T p.T235= | Silent (SNP) | VAF 75/301 reads (25%) | called by muse, mutect2, varscan2
- C2CD3 | c.1758T>G p.P586= | Silent (SNP) | VAF 34/126 reads (27%) | called by muse, varscan2
- C2CD4B | c.810C>A p.L270= | Silent (SNP) | VAF 43/300 reads (14%) | called by muse, mutect2, varscan2
- CCDC92 | c.891C>T p.H297= | Silent (SNP) | VAF 77/170 reads (45%) | catalogued as rs759171991, COSV53022305; called by muse, mutect2, varscan2
- CHD3 | c.2733A>G p.T911= | Silent (SNP) | VAF 109/206 reads (53%) | called by muse, varscan2
- CYP4F2 | c.717C>A p.I239= | Silent (SNP) | VAF 151/484 reads (31%) | called by muse, mutect2, varscan2
- FMO5 | c.1566T>G p.A522= | Silent (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- FOXD2 | c.1083C>T p.G361= | Silent (SNP) | VAF 76/392 reads (19%) | called by muse, mutect2, varscan2
- FOXG1 | c.1260C>T p.H420= | Silent (SNP) | VAF 59/683 reads (9%) | catalogued as rs1328906982; called by muse, mutect2
- GALC | c.543C>T p.G181= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs772338291, COSV99730242; ClinVar: likely benign; called by muse, mutect2
- GNAS | c.879T>C p.S293= | Silent (SNP) | VAF 166/439 reads (38%) | catalogued as rs777051187; called by muse, mutect2, varscan2
- HOXD11 | c.366G>A p.E122= | Silent (SNP) | VAF 7/61 reads (11%) | called by mutect2, varscan2
- ITGA2B | c.1401C>T p.I467= | Silent (SNP) | VAF 182/715 reads (25%) | catalogued as rs766997708, COSV52231081, COSV52234954; called by muse, mutect2, varscan2
- ITLN1 | c.498G>A p.L166= | Silent (SNP) | VAF 72/159 reads (45%) | called by muse, mutect2, varscan2
- KIAA0319 | c.2460G>A p.L820= | Silent (SNP) | VAF 67/182 reads (37%) | called by muse, mutect2, varscan2
- LPXN | c.1149C>G p.L383= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, varscan2
- LRTM2 | c.741C>T p.F247= | Silent (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- LSG1 | c.633C>T p.I211= | Silent (SNP) | VAF 205/421 reads (49%) | catalogued as rs375483008; called by muse, mutect2, varscan2
- MCL1 | c.432G>A p.L144= | Silent (SNP) | VAF 324/630 reads (51%) | catalogued as rs900035249; called by muse, mutect2, varscan2
- MIB2 | c.222A>T p.A74= | Silent (SNP) | VAF 75/322 reads (23%) | called by muse, mutect2, varscan2
- MOG | c.60C>G p.L20= | Silent (SNP) | VAF 153/518 reads (30%) | called by muse, mutect2, varscan2
- MYO16 | c.4338C>T p.G1446= | Silent (SNP) | VAF 252/640 reads (39%) | called by muse, mutect2, varscan2
- NBAS | c.6477A>T p.L2159= | Silent (SNP) | VAF 112/238 reads (47%) | called by muse, mutect2, varscan2
- NFIX | c.1155G>T p.T385= | Silent (SNP) | VAF 125/421 reads (30%) | catalogued as rs766182073, COSV62176436; called by muse, mutect2, varscan2
- NPAP1 | c.2460T>C p.I820= | Silent (SNP) | VAF 86/399 reads (22%) | called by muse, mutect2, varscan2
- OR2T10 | c.81C>A p.L27= | Silent (SNP) | VAF 126/251 reads (50%) | catalogued as COSV57897923, COSV57898498; called by muse, mutect2, varscan2
- OR2T33 | c.540C>T p.P180= | Silent (SNP) | VAF 96/235 reads (41%) | catalogued as rs149706190, COSV100532014; called by mutect2, varscan2
- OR2T8 | c.540C>T p.P180= | Silent (SNP) | VAF 164/389 reads (42%) | catalogued as rs771429565; called by muse, mutect2, varscan2
- OR5AK2 | c.246C>T p.L82= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs775594169; called by muse, mutect2, varscan2
- OR6N2 | c.312C>T p.F104= | Silent (SNP) | VAF 83/161 reads (52%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2073T>C p.A691= | Silent (SNP) | VAF 54/275 reads (20%) | called by muse, mutect2, varscan2
- PCDHB13 | c.924C>T p.L308= | Silent (SNP) | VAF 14/344 reads (4%) | catalogued as rs782628868, COSV53393603; called by muse, mutect2
- PCDHB7 | c.984T>G p.S328= | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1318C>T p.L440= | Silent (SNP) | VAF 111/704 reads (16%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1527C>T p.S509= | Silent (SNP) | VAF 20/414 reads (5%) | catalogued as COSV52762211; called by muse, mutect2
- POLD3 | c.1128T>C p.S376= | Silent (SNP) | VAF 67/187 reads (36%) | catalogued as rs1414328517; called by muse, mutect2, varscan2
- POLL | c.1218T>C p.F406= | Silent (SNP) | VAF 101/189 reads (53%) | called by muse, mutect2, varscan2
- RASGRP2 | c.843G>A p.T281= | Silent (SNP) | VAF 21/479 reads (4%) | catalogued as rs982923548, COSV100818129; called by muse, mutect2
- REG3G | c.114C>A p.I38= | Silent (SNP) | VAF 80/271 reads (30%) | catalogued as COSV55448466; called by muse, mutect2, varscan2
- RINL | c.1122G>A p.R374= (on ENST00000591812 / NM_001195833.2; = p.R260= on NM_198445.4) | Silent (SNP) | VAF 37/244 reads (15%) | called by muse, mutect2, varscan2
- SDHA | c.585G>T p.R195= | Silent (SNP) | VAF 332/792 reads (42%) | catalogued as COSV53769486; called by muse, mutect2, varscan2
- SERPIND1 | c.1440C>T p.Y480= | Silent (SNP) | VAF 75/617 reads (12%) | catalogued as rs763461848; called by muse, mutect2, varscan2
- SLC46A2 | c.1227C>A p.V409= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as COSV65289704; called by muse, mutect2, varscan2
- SLC5A1 | c.1854C>A p.P618= | Silent (SNP) | VAF 161/404 reads (40%) | catalogued as COSV99833270; called by muse, mutect2, varscan2
- SLC9A3 | c.195C>G p.A65= | Silent (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- SLC9C2 | c.2649C>G p.A883= | Silent (SNP) | VAF 43/215 reads (20%) | called by muse, mutect2, varscan2
- TDRD9 | c.519C>T p.Y173= | Silent (SNP) | VAF 91/881 reads (10%) | catalogued as rs985607626; called by muse, mutect2, varscan2
- THSD7B | c.867T>C p.H289= | Silent (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- TMEM63A | c.1725G>T p.L575= | Silent (SNP) | VAF 53/322 reads (16%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.1611G>A p.G537= | Silent (SNP) | VAF 73/283 reads (26%) | called by muse, mutect2, varscan2
- TNN | c.1104C>T p.D368= | Silent (SNP) | VAF 80/348 reads (23%) | catalogued as rs745496505; called by muse, mutect2, varscan2
- ZFHX4 | c.9912C>T p.P3304= | Silent (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- ZNF112 | c.550A>C p.R184= (on ENST00000337401 / NM_001083335.2; = p.R178= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- ZNF318 | c.1323T>A p.T441= | Silent (SNP) | VAF 134/539 reads (25%) | called by muse, mutect2, varscan2
- ZNF383 | c.45C>T p.F15= | Silent (SNP) | VAF 269/461 reads (58%) | called by muse, mutect2, varscan2
- ZNF488 | c.858A>G p.L286= | Silent (SNP) | VAF 53/262 reads (20%) | catalogued as rs1555213084; called by muse, mutect2, varscan2
- ZWINT | c.37C>T p.L13= | Silent (SNP) | VAF 68/209 reads (33%) | catalogued as rs373212014; called by muse, mutect2, varscan2
- AC073348.1 | n.258C>A | RNA (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- CDH8 | c.*5740G>C | 3'UTR (SNP) | VAF 46/200 reads (23%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.4726+63G>T | Intron (SNP) | VAF 105/405 reads (26%) | called by muse, mutect2, varscan2
- CYP21A1P | chr6:32009784 G>T | 3'Flank (SNP) | VAF 169/1173 reads (14%) | called by muse, mutect2, varscan2
- DNAJC6 | c.22+44858T>C | Intron (SNP) | VAF 39/325 reads (12%) | catalogued as rs761277268; called by muse, mutect2, varscan2
- FAM90A20P | n.713G>A | RNA (SNP) | VAF 32/600 reads (5%) | catalogued as rs771070883; called by muse, mutect2
- FCGR2B | c.818-66G>T | Intron (SNP) | VAF 251/492 reads (51%) | called by muse, mutect2, varscan2
- GTPBP3 | chr19:17335062 C>T | 5'Flank (SNP) | VAF 73/319 reads (23%) | catalogued as COSV50173653; called by muse, mutect2, varscan2
- HERC2P3 | n.2028G>A | RNA (SNP) | VAF 18/128 reads (14%) | called by mutect2, varscan2
- IGFN1 | c.1242-217G>A | Intron (SNP) | VAF 417/797 reads (52%) | called by muse, mutect2, varscan2
- KCNK10 | c.37+3615G>A | Intron (SNP) | VAF 22/298 reads (7%) | catalogued as COSV100069400; called by muse, mutect2
- KLF6 | c.*3032A>T | 3'UTR (SNP) | VAF 45/146 reads (31%) | called by muse, mutect2, varscan2
- LINC01591 | n.516C>G | RNA (SNP) | VAF 50/429 reads (12%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.236G>A | RNA (SNP) | VAF 97/323 reads (30%) | called by muse, mutect2, varscan2
- OR4C4P | n.182T>A | RNA (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- PFKFB2 | chr1:207079015 G>A | 3'Flank (SNP) | VAF 82/439 reads (19%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.331-365C>A | Intron (SNP) | VAF 100/308 reads (32%) | called by muse, mutect2, varscan2
- RNF207 | c.325-15G>A | Intron (SNP) | VAF 53/319 reads (17%) | called by muse, mutect2, varscan2
- SDHAP2 | n.1005G>A | RNA (SNP) | VAF 70/1726 reads (4%) | catalogued as rs1464088446; called by muse, mutect2
- SEPTIN2 | c.217+122G>A | Intron (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2
- SLC2A8 | chr9:127397164 G>C | 5'Flank (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2, varscan2
- SSBP4 | c.992-82G>T | Intron (SNP) | VAF 211/624 reads (34%) | called by muse, mutect2, varscan2
- STX6 | c.-24G>A | 5'UTR (SNP) | VAF 88/408 reads (22%) | called by muse, mutect2, varscan2
- TTLL10 | c.-28+1162C>T | Intron (SNP) | VAF 16/76 reads (21%) | catalogued as rs572064116; called by muse, mutect2, varscan2
- TTLL5 | c.3740+3849A>G | Intron (SNP) | VAF 122/219 reads (56%) | called by muse, mutect2, varscan2
- TTN | c.34264+3318G>A | Intron (SNP) | VAF 67/150 reads (45%) | catalogued as rs1245376734; called by muse, mutect2, varscan2
- ZNF750 | c.-1A>C | 5'UTR (SNP) | VAF 91/381 reads (24%) | catalogued as rs1325502233; called by muse, mutect2, varscan2
